Surgical pathology report (de-identified scan), TCGA case TCGA-FK-A3S3, project TCGA-THCA (Thyroid Carcinoma), tissue source site Johns Hopkins, specimen TCGA-FK-A3S3-01A (Primary Tumor).

[page 1 of 2]
- LAB RESULTS

PATH#:

SURG PATH REPORT
COLLECTION DATE/TIME:

1st Specimen collected on
Accessioned on

* This report has been amended *

FINAL DIAGNOSIS ----- Pathologist:

1) SOFT TISSUE, NECK (EXCISION): PARATHYROID TISSUE (2 MG).
NEGATIVE FOR TUMOR.

2) SOFT TISSUE #2, NECK (EXCISION): PARATHYROID TISSUE (4 MG).
NEGATIVE FOR TUMOR.

3) THYROID (TOTAL THYROIDECTOMY):

SPECIMEN TYPE:

Total thyroidectomy

TUMOR SITE:

Left lobe

HISTOLOGIC TYPE:

Papillary carcinoma, follicular variant 99% per TSS / W

TUMOR SIZE:

2.5 cm greatest dimension

FOCALITY:

Multifocal

LYMPH NODES:

Metastatic carcinoma in 4 of 11 lymph node (BASED ON PARTS 3 AND 4)
THE LARGEST METASTASIS MEASURES 2.4 CM.

EXTENT OF INVASION

PRIMARY TUMOR:

pT3: Tumor with minimal extrathyroidal extension

REGIONAL LYMPH NODES:

pN1b: Metastasis to cervical or mediastinal nodes

DISTANT METASTASIS:

pMx: Cannot be assessed

MARGINS:

Margins uninvolved

VENOUS/LYMPHATIC INVASION:

Present

4) SOFT TISSUE, CENTRAL AND MEDIASTINAL COMPARTMENTS (DISSECTION):
METASTATIC PAPILLARY CARCINOMA IN ONE (1) OF SEVEN (7) LYMPH NODES.

AMMENDMENT: THIS DIAGNOSIS WAS AMMENDEED AFTER THE SURGEON REQUESTED
THAT WE SUBMIT ADDITIONAL TISSUE FROM PART THREE LOOKING FOR LYMPH
NODES AND THAT WE ADD THE SIZE OF THE LARGEST METASTASIS. AFTER
ADDITIONAL TISSUE WAS SUBMITTED ON PART THREE, THE DIAGNOSIS WAS
AMMENDED TO: 1) ADD THE SIZE OF THE LARGEST LYMPH NODE METASTASIS
(2.4CM), AND 2) TO ADD ADDITIONAL LYMPH NODES TO PART THREE (THREE OF
FOUR ADDITIONAL LYMPH NODES WERE POSITIVE FOR TUMOR). THE DIAGNOSIS
IS OTHERWISE UNCHANGED.

Reported by:

ICD-O-3
carcinoma, papillary, follicular variant

site: thyroid, NOS

7340/3
C73.9 5-1-12
RD

*** Unofficial lab results - do not file in patient chart. ***

*** Contact medical records for official chart copy. ***

UNLESS OTHERWISE NOTED ON THE DETAIL PAGE, ALL LAB RESULTS PERFORMED AT:

[page 2 of 2]
~~XXXXXXXXXXXXXXXXXXXX~~
- LAB RESULTS

Tel: .

Report Amended on
(Report Originally Signed on
Final Report Signed on

*** Unofficial lab results - do not file in patient chart. ***
*** Contact medical records for official chart copy. ***
(UNLESS OTHERWISE NOTED ON THE DETAIL PAGE. ALL LAB RESULTS PERFORMED AT:

Source: NCI Genomic Data Commons file f23b319d-bcfb-495e-87d9-bbd973091722 (TCGA-FK-A3S3.6CE1962B-78BA-4FBC-B3FD-8AB5C4D1869A.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).